Somatic mutation profile of tumor specimen 0DWVFI from CCDI case PBCPNM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 3.9 years (1,430 days).
Specimen 0DWVFI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59a6af45-ef2c-4070-a0c4-b974f99fc5eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWVEO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e07cedbf-b1de-4168-8503-3050e4616a73

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CUX2 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 247/501 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs537978708; called by muse, mutect2, varscan2
- DCC | c.767A>G p.D256G | Missense Mutation (SNP) | VAF 414/890 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.082); catalogued as COSV59124784, COSV59128042; called by muse, mutect2, varscan2
- EPHB1 | c.1850C>A p.S617Y | Missense Mutation (SNP) | VAF 339/845 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV101214394; called by muse, mutect2, varscan2
- GDF10 | c.790C>T p.Q264* | Nonsense Mutation (SNP) | VAF 18/715 reads (3%) | catalogued as rs563284415; called by muse, mutect2
- PRAMEF9 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 18/398 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.886); catalogued as rs782689944; called by muse, mutect2
- GPHA2 | c.143G>T p.C48F | Missense Mutation (SNP) | VAF 22/674 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2
- MUC5B | c.14925G>T p.Q4975H | Missense Mutation (SNP) | VAF 279/603 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- MYRIP | c.1412G>T p.R471I | Missense Mutation (SNP) | VAF 329/682 reads (48%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- FIBCD1 | c.1149C>T p.S383= | Silent (SNP) | VAF 217/497 reads (44%) | catalogued as rs764214748; called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 41/1138 reads (4%) | called by muse, mutect2
- ASIC1 | c.559-3306G>A | Intron (SNP) | VAF 188/396 reads (47%) | called by muse, mutect2
